Somatic mutation profile of tumor specimen 0DK3EB from CCDI case PBBXCD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.6 years (7,152 days).
Specimen 0DK3EB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cf33b7b-e7fd-4971-a721-86037b1806f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK3EO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56cb72b3-03ac-4d55-a886-e04e5bedf591

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Translation Start Site 1, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAF1 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 162/1802 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs397516827, CM073300, COSV52574365, COSV52575478; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CBL | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 158/895 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs756530482, COSV50631755; called by muse, varscan2
- GAREM1 | c.2555C>G p.S852* (on ENST00000269209 / NM_001242409.2; = p.S851* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 30/982 reads (3%) | called by muse, mutect2
- KIT | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 150/1844 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2
- POU5F1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/385 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PTCH1 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 126/1569 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.401); called by muse, mutect2
- SRCIN1 | c.3094G>A p.E1032K (on ENST00000621492; = p.E998K on NM_025248.3) | Missense Mutation (SNP) | VAF 115/1045 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 12/184 reads (7%) | catalogued as rs1262556378; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 48/1160 reads (4%) | called by muse, mutect2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 32/1110 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 63/499 reads (13%) | called by muse, varscan2
